FM case AD1314 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts.
https://portal.gdc.cancer.gov/cases/2f8c403a-dc34-4017-b24f-2f7cf230f167

Female, 53.7 years: Hepatocellular carcinoma, NOS (ICD-O-3 8170/3) of the liver. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Tumor.
